Somatic mutation profile of tumor specimen 0DSJY7 from CCDI case PBCIDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.3 years (3,022 days).
Specimen 0DSJY7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aaf7a22-d1d6-48fc-a122-0e0b290959d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSJYL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89a147e3-686c-48ca-9c62-a8b7b7735e12

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 4, Intron 3, 3'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs369198922; called by muse, mutect2, varscan2
- CD1C | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 56/573 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs369535551; called by muse, mutect2, varscan2
- CLIC5 | c.826G>A p.D276N (on ENST00000185206 / NM_001370649.1; = p.D117N on NM_016929.5) | Missense Mutation (SNP) | VAF 20/636 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV51757328; called by muse, mutect2
- CYP27C1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs763255213; called by muse, mutect2, varscan2
- DOCK3 | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188958196; called by muse, mutect2
- FAM50B | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66654624; called by muse, mutect2, varscan2
- FZD9 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 195/406 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.112); catalogued as rs1390816222; called by muse, mutect2, varscan2
- GPM6A | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 255/485 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs779875512; called by muse, mutect2, varscan2
- MDH1B | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs766638320, COSV65590726; called by muse, mutect2, varscan2
- ZMYM3 | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 243/253 reads (96%) | catalogued as COSV58739780; called by muse, mutect2, varscan2
- ACOD1 | c.88A>C p.S30R | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AVPR1B | c.978G>C p.L326F | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CA6 | c.438C>G p.Y146* | Nonsense Mutation (SNP) | VAF 252/504 reads (50%) | called by muse, mutect2, varscan2
- CD163L1 | c.*24+1G>A | Splice Site (SNP) | VAF 101/213 reads (47%) | called by muse, mutect2, varscan2
- CD1E | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 137/712 reads (19%) | called by muse, mutect2, varscan2
- CYP27A1 | c.1286A>C p.Y429S | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICAM1 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- KRT7 | c.804T>A p.Y268* | Nonsense Mutation (SNP) | VAF 35/342 reads (10%) | called by muse, mutect2, varscan2
- MFSD1 | c.399T>A p.F133L | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAV3 | c.530dup p.S178Qfs*57 | Frame Shift Ins (INS) | VAF 129/336 reads (38%) | called by mutect2, pindel, varscan2
- PDZD2 | c.5278T>C p.F1760L | Missense Mutation (SNP) | VAF 87/591 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKD1 | c.1041C>G p.D347E | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHC3 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ZIC1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ABCC1 | c.1830T>C p.S610= | Silent (SNP) | VAF 7/211 reads (3%) | catalogued as rs1324181417; called by muse, mutect2
- CEP135 | c.2628T>C p.N876= | Silent (SNP) | VAF 50/419 reads (12%) | called by muse, mutect2, varscan2
- GATC | c.327C>T p.R109= | Silent (SNP) | VAF 50/437 reads (11%) | catalogued as rs763975149, COSV57571148; called by muse, mutect2, varscan2
- IRF4 | c.363G>A p.P121= | Silent (SNP) | VAF 48/473 reads (10%) | catalogued as rs778712289, COSV66704458; called by muse, mutect2, varscan2
- KRT77 | c.1176G>T p.L392= | Silent (SNP) | VAF 106/232 reads (46%) | called by muse, mutect2, varscan2
- NSD2 | c.39G>A p.Q13= | Silent (SNP) | VAF 15/374 reads (4%) | called by muse, mutect2
- OR9A4 | c.777C>T p.Y259= | Silent (SNP) | VAF 26/922 reads (3%) | catalogued as rs199797468, COSV71884947; called by muse, mutect2
- STUB1 | c.684C>T p.P228= | Silent (SNP) | VAF 162/356 reads (46%) | catalogued as rs756496385, COSV99556060; called by muse, mutect2, varscan2
- ZSWIM8 | c.177C>T p.G59= | Silent (SNP) | VAF 230/520 reads (44%) | catalogued as rs766830130; called by muse, mutect2, varscan2
- CC2D2B | c.781-4570G>A | Intron (SNP) | VAF 97/251 reads (39%) | catalogued as rs1201800031; called by muse, mutect2, varscan2
- GCG | chr2:162143363 G>C | 3'Flank (SNP) | VAF 89/246 reads (36%) | called by muse, mutect2, varscan2
- KRT15 | c.1247+69G>T | Intron (SNP) | VAF 55/245 reads (22%) | called by muse, mutect2, varscan2
- NCKAP1 | c.2022-98A>G | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
